Surgical pathology report (de-identified scan), TCGA case TCGA-87-5896, project TCGA-GBM (Glioblastoma Multiforme), tissue source site International Genomics Consortium, specimen TCGA-87-5896-01A (Primary Tumor).

QC Pathologist:

*** ADDENDUM REPORT ***

This addendum is issued to report the findings of ~
at the

"DIAGNOSIS:

Brain, left frontal mass lesion (outside slides ~
~ biopsy and resection:

Glioblastoma multiforme, WHO Grade IV.

MICROSCOPIC:

Sections show a cellular astrocytic tumor composed predominantly of bipolar tumor cells. There are numerous mitoses. Endothelial proliferation is present. The initial biopsy and portions of the resection specimen show hemorrhage into necrotic tumor. Pseudopalisading necrosis is focally present (C4). The tumor infiltrates adjacent brain with secondary structuring.

GFAP stains highlight the bipolar tumor cell morphology.

Ki67 (MIB-1) shows a proliferative index of about 25%."

Addendum Report Issued By:

at

FINAL PATHOLOGIC DIAGNOSIS:

A. Left frontal mass; biopsy:

Predominantly necrosis, no viable tumor identified.

Intraoperative consultation corroborated.

B&C. Left frontal mass; excision:

High grade glioma, favor glioblastoma multiforme.

Intraoperative consultation corroborated.

Expert consultation pending, results to be reported as an addendum.

COMMENTS:

Histologic sections show a markedly hypercellular tumor composed of atypical glial cells (confirmed by positive GFAP stain). Numerous mitotic figures are present. The presence of tumor necrosis as well as vascular proliferation support the diagnosis of a glioblastoma multiforme. The MIB-1 proliferative index is up to 35-40%.

CLINICAL HISTORY:

CGA-87-5896

Source: NCI Genomic Data Commons file 9da53daf-136a-4bc5-adfe-2bf4e878ca33 (TCGA-87-5896.A743B83F-A4FF-4B06-9728-765A6BB6807F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).